Gene-level copy-number profile of tumor specimen TCGA-24-0970-01B from TCGA case TCGA-24-0970, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.7 years (23,276 days).
Specimen TCGA-24-0970-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.40e41ce7-8a6b-440d-be49-8502f20b1c96.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-0970-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4921eb78-aff7-4c35-a68c-5863f9538ae9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 22,275; copy number 2: 28,788; copy number 3: 7,789; copy number 4: 771; copy number 5: 32; copy number 6: 44; copy number 7: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-0970-01B-01D-0428-01): tumor purity 0.68, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:20,251,905–22,516,066, 16 genes (within-gene range 0–1): SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P, ADGRA3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 167 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:150,408,335–150,873,554, 11 genes, copy number 5 (within-gene range 3–5): TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, AC011317.1, SIAH2, SIAH2-AS1.
- chr3:177,294,442–177,349,166, 3 genes, copy number 5 (within-gene range 3–5): LINC00501, ASS1P7, AC117465.1.
- chr7:816,615–1,138,260, 14 genes, copy number 6 (within-gene range 4–6): SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1.
- chr7:129,604,548–130,216,844, 18 genes, copy number 5: AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1.
- chr11:61,792,980–62,556,235, 30 genes, copy number 6 (within-gene range 3–6): FADS2, FADS1, MIR1908, FADS3, MIR6746, RAB3IL1, RNU6-1243P, BEST1, FTH1, AP003733.3, AP003733.1, LINC02733, AP003733.2, AP002793.1, INCENP, EEF1DP8, SCGB1D1, SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6, AP003064.1, SCGB1A1, AP003064.2, AHNAK.
- chr17:47,603,860–49,176,840, 91 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,055. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
